Somatic mutation profile of tumor specimen MMRF_1516_1_BM_CD138pos (aliquot MMRF_1516_1_BM_CD138pos_T1_KBS5U_L02995) from MMRF case MMRF_1516, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 83.2 years (30,380 days).
Specimen MMRF_1516_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84026d33-fb68-4c6d-a98a-0c280b11dd12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1516_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1516_1_PB_Whole_C3_KBS5U_L03003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0280663b-5259-4d66-aba8-3ff596a9e4ab

The open-access MAF lists 98 somatic variants for this specimen: 34 protein-altering or splice-affecting, 12 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, 3'UTR 28, Silent 12, Intron 9, 5'Flank 7, 5'UTR 4, 3'Flank 3, Frame Shift Del 1, RNA 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 35/91 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 22/451 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ALDH9A1 | c.692A>G p.N231S | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as rs773362229; called by muse, mutect2, varscan2
- ENPEP | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs915463280, COSV54453232; called by muse, varscan2
- FLNC | c.3079C>T p.R1027C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs541775814, COSV57956465; called by muse, mutect2, varscan2
- IGHV2-70 | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs373039668; called by muse, varscan2
- IGHV2-70D | c.170G>A p.W57* | Nonsense Mutation (SNP) | VAF 37/37 reads (100%) | catalogued as rs1256056776; called by muse, varscan2
- ITPRID2 | c.95G>A p.S32N | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs1226411791; called by muse, mutect2, varscan2
- OTOL1 | c.1171del p.S391Pfs*6 | Frame Shift Del (DEL) | VAF 33/97 reads (34%) | catalogued as COSV100019816; called by mutect2, pindel, varscan2
- RNASE9 | c.556G>A p.V186M | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.078); catalogued as rs149710160, COSV58880441; called by muse, mutect2, varscan2
- SH3RF2 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 85/172 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs778124192; called by muse, mutect2, varscan2
- ZNF605 | c.1842T>G p.D614E | Missense Mutation (SNP) | VAF 73/205 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769838219; called by muse, mutect2, varscan2
- ATP5PB | c.529G>C p.A177P | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.94); called by muse, varscan2
- BRWD1 | c.727A>G p.I243V | Missense Mutation (SNP) | VAF 80/177 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CARD6 | c.329C>A p.A110E | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CENPE | c.6083A>G p.H2028R | Missense Mutation (SNP) | VAF 4/93 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.188); called by muse, mutect2
- CPZ | c.1768A>G p.N590D (on ENST00000360986 / NM_001014447.3; = p.N579D on NM_003652.3) | Missense Mutation (SNP) | VAF 58/108 reads (54%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP2A6 | c.631T>G p.F211V | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- CYP4F3 | c.644A>G p.Q215R | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); called by muse, mutect2
- DYSF | c.892C>T p.L298F | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- FAT3 | c.3110A>C p.N1037T | Missense Mutation (SNP) | VAF 72/135 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GNE | c.587A>C p.E196A (on ENST00000396594 / NM_001128227.3; = p.E165A on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/105 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GPR108 | c.653G>A p.G218D | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- IGHD6-6 | c.6_10dup p.S4Ifs*? | Frame Shift Ins (INS) | VAF 33/37 reads (89%) | called by pindel, varscan2
- IGHV4-39 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, varscan2
- IGHV4-39 | c.19A>C p.K7Q | Missense Mutation (SNP) | VAF 20/20 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.069); called by muse, varscan2
- MGAT4C | c.820C>A p.H274N | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- PDGFC | c.806T>C p.I269T | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- PRR14L | c.6224C>G p.T2075R | Missense Mutation (SNP) | VAF 67/126 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- SLC5A3 | c.26A>G p.D9G | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYT14 | c.1021T>G p.Y341D | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- TRAPPC10 | c.1786T>A p.S596T | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- VANGL1 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- ZFR2 | c.244A>G p.T82A | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HNRNPF | c.1167C>T p.Y389= | Silent (SNP) | VAF 81/164 reads (49%) | catalogued as rs375590998, COSV100563101, COSV61561063; called by muse, mutect2, varscan2
- IGHV2-70 | c.273C>G p.S91= | Silent (SNP) | VAF 32/62 reads (52%) | catalogued as rs115694694; called by muse, varscan2
- IGHV2-70D | c.30A>T p.L10= | Silent (SNP) | VAF 42/70 reads (60%) | called by muse, varscan2
- LRRD1 | c.30G>A p.V10= | Silent (SNP) | VAF 36/97 reads (37%) | called by muse, mutect2, varscan2
- MYH14 | c.3379C>T p.L1127= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as rs916028274; called by muse, mutect2
- PCDH11X | c.66C>T p.G22= | Silent (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- RAPGEF1 | c.15T>G p.S5= | Silent (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- SSH2 | c.7T>C p.L3= | Silent (SNP) | VAF 17/40 reads (43%) | called by muse, mutect2, varscan2
- TNR | c.1287C>A p.T429= | Silent (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- TNXB | c.12195C>T p.G4065= (on ENST00000647633; = p.G3818= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as rs371882323; called by muse, mutect2
- XIRP2 | c.5451G>T p.G1817= (on ENST00000628543; = p.G1992= on NM_152381.6) | Silent (SNP) | VAF 29/95 reads (31%) | called by muse, mutect2, varscan2
- ZC3H14 | c.484T>C p.L162= | Silent (SNP) | VAF 9/205 reads (4%) | called by muse, mutect2
- AC093909.6 | chr4:188739368 A>C | 3'Flank (SNP) | VAF 94/246 reads (38%) | called by muse, mutect2
- ATF3 | c.349-269T>C | Intron (SNP) | VAF 38/67 reads (57%) | catalogued as rs199908865; called by muse, mutect2, varscan2
- BBS9 | c.*113C>T | 3'UTR (SNP) | VAF 43/81 reads (53%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021297 T>A | 5'Flank (SNP) | VAF 48/92 reads (52%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021402 C>G | 5'Flank (SNP) | VAF 36/74 reads (49%) | catalogued as rs925835724, COSV55846299, COSV55846759, COSV55847493; called by muse, varscan2
- BCL7A | chr12:122021485 C>T | 5'Flank (SNP) | VAF 32/58 reads (55%) | catalogued as COSV55848041; called by muse, varscan2
- C2orf50 | c.*724G>A | 3'UTR (SNP) | VAF 15/35 reads (43%) | catalogued as rs1161040356; called by muse, mutect2, varscan2
- CAPS2 | c.1670-2365T>C | Intron (SNP) | VAF 54/107 reads (50%) | catalogued as rs1278621678; called by muse, mutect2, varscan2
- CCDC141 | c.1899+1083G>T | Intron (SNP) | VAF 48/131 reads (37%) | called by muse, mutect2, varscan2
- CCDC148 | c.*974T>C | 3'UTR (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- CEP290 | c.2818-1049_2818-1046del | Intron (DEL) | VAF 9/24 reads (38%) | called by mutect2, varscan2
- CLIP2 | c.*1766C>T | 3'UTR (SNP) | VAF 10/139 reads (7%) | called by muse, mutect2
- CPLANE1 | chr5:37247687 T>C | 5'Flank (SNP) | VAF 76/150 reads (51%) | catalogued as rs1429946121; called by muse, varscan2
- CPLANE1 | chr5:37247756 T>G | 5'Flank (SNP) | VAF 45/92 reads (49%) | called by muse, varscan2
- CXCL11 | c.*957T>G | 3'UTR (SNP) | VAF 23/100 reads (23%) | called by muse, mutect2, varscan2
- DHRS1 | c.150+129G>T | Intron (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- EOLA1 | chrX:149550212 G>T | 3'Flank (SNP) | VAF 26/38 reads (68%) | called by mutect2, varscan2
- FARP2 | c.1893+1482G>A | Intron (SNP) | VAF 52/110 reads (47%) | called by muse, mutect2, varscan2
- FGF14 | c.*6665C>T | 3'UTR (SNP) | VAF 16/74 reads (22%) | catalogued as rs1282834218; called by muse, mutect2, varscan2
- FLRT2 | c.*3474G>T | 3'UTR (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- FOXP4 | c.204+4246G>T | Intron (SNP) | VAF 13/150 reads (9%) | called by muse, mutect2
- GLUD2 | c.*259G>A | 3'UTR (SNP) | VAF 133/135 reads (99%) | catalogued as rs1247329285; called by muse, mutect2, varscan2
- GNPDA1 | c.*378T>C | 3'UTR (SNP) | VAF 36/73 reads (49%) | called by muse, mutect2, varscan2
- HEBP2 | chr6:138403571 T>C | 5'Flank (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- HS2ST1 | c.*3797G>C | 3'UTR (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- ITGA1 | c.*825A>G | 3'UTR (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- IVNS1ABP | c.766-74G>A | Intron (SNP) | VAF 18/72 reads (25%) | called by mutect2, varscan2
- KLHDC7A | c.*971G>A | 3'UTR (SNP) | VAF 15/63 reads (24%) | called by muse, mutect2, varscan2
- LHFPL2 | c.*2725C>G | 3'UTR (SNP) | VAF 75/158 reads (47%) | called by muse, mutect2, varscan2
- LINC01257 | n.343C>T | RNA (SNP) | VAF 15/24 reads (63%) | called by muse, varscan2
- LRRC55 | c.*176G>A | 3'UTR (SNP) | VAF 5/76 reads (7%) | called by muse, mutect2
- MLEC | c.*3012T>C | 3'UTR (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- MTHFD2 | c.*1261A>G | 3'UTR (SNP) | VAF 24/69 reads (35%) | catalogued as rs756489128; called by muse, mutect2, varscan2
- NECTIN3 | c.*1257T>G | 3'UTR (SNP) | VAF 41/97 reads (42%) | catalogued as rs1030510229; called by muse, mutect2, varscan2
- NUAK2 | c.*221A>G | 3'UTR (SNP) | VAF 6/88 reads (7%) | catalogued as rs1227805327; called by muse, mutect2
- ORAI2 | c.*3420C>A | 3'UTR (SNP) | VAF 41/121 reads (34%) | called by muse, mutect2, varscan2
- PDPN | c.*1711C>T | 3'UTR (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- PHF12 | c.*930C>T | 3'UTR (SNP) | VAF 23/42 reads (55%) | called by muse, mutect2, varscan2
- RAB3C | c.*3665T>C | 3'UTR (SNP) | VAF 45/91 reads (49%) | catalogued as rs970689628; called by muse, mutect2, varscan2
- RERE | c.*14T>A | 3'UTR (SNP) | VAF 21/232 reads (9%) | called by muse, mutect2
- SAR1B | c.*2862A>G | 3'UTR (SNP) | VAF 30/81 reads (37%) | called by muse, mutect2, varscan2
- SEPTIN11 | c.-16C>T | 5'UTR (SNP) | VAF 9/22 reads (41%) | catalogued as rs1376342745; called by muse, mutect2
- SHISA2 | c.*299T>C | 3'UTR (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- SLA2 | c.*413G>A | 3'UTR (SNP) | VAF 26/48 reads (54%) | called by muse, mutect2, varscan2
- TENM2 | c.713-141G>C | Intron (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- TRIM52 | chr5:181261125 del CTACC | 5'Flank (DEL) | VAF 14/39 reads (36%) | called by mutect2, pindel, varscan2
- TTYH3 | c.*2422C>T | 3'UTR (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2, varscan2
- ZC3H3 | c.-19G>C | 5'UTR (SNP) | VAF 118/209 reads (56%) | called by muse, mutect2
- ZNF711 | chrX:85272493 ins T | 3'Flank (INS) | VAF 20/27 reads (74%) | called by mutect2, pindel, varscan2
- ZNF77 | c.-10C>T | 5'UTR (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2
- ZNF799 | c.-126G>A | 5'UTR (SNP) | VAF 45/86 reads (52%) | called by muse, mutect2, varscan2
- ZZEF1 | c.*2206G>A | 3'UTR (SNP) | VAF 87/194 reads (45%) | called by muse, mutect2, varscan2
